Surgical pathology report (de-identified scan), TCGA case TCGA-24-1550, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1550-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

FINAL

24-1550

*** Converted Case * This report may not match the original report format**

Patient Name:

Address:

Gender:

DOB:

Service:

Location:

MRN :

Hospital #:

Patient Type:

Accession #:

Taken:

Received:

Accessioned:

Reported:

Physician(s):

DIAGNOSIS:

OVARY, LEFT, SALPINGO-OOPHORECTOMY

- POORLY DIFFERENTIATED ADENOCARCINOMA, MIXED EPITHELIAL TYPE (PAPILLARY SEROUS AND CLEAR CELL COMPONENTS)

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY - NO CARCINOMA IDENTIFIED

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- METASTATIC ADENOCARCINOMA PREDOMINANTLY INVOLVING PARAOVARIAN ADHESIONS

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- CYSTIC WALTHARD REST
- PARATUBAL PARAMESONEPHRIC CYST (HYDATID OF MORGAGNI)

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- METASTATIC ADENOCARCINOMA INVOLVING DEEP CERVICAL SOFT TISSUE
- MILD CHRONIC INFLAMMATION AND SQUAMOUS METAPLASIA

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY - PROLIFERATIVE ENDOMETRIUM

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY - MULTIPLE LEIOMYOMAS

SPECIMEN LABELED "TUMOR," SITE NOT SPECIFIED, EXCISION - METASTATIC ADENOCARCINOMA

BLADDER, TUMOR, BIOPSY - METASTATIC ADENOCARCINOMA

OMENTUM, OMENTECTOMY - METASTATIC ADENOCARCINOMA

APPENDIX, APPENDECTOMY - FIBROUS OBLITERATION OF THE DISTAL TIP

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides(and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By Conversion

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Intraoperative Consultation:

FS1: Ovary, left, left salpingo-oophorectomy - "Adenocarcinoma,
favor mullerian
origin," [REDACTED]

Microscopic Description and Comment:

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is: Adenocarcinoma, mixed epithelial
type (papillary serous and clear cell).
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
left ovary
4. The FIGO-GRADE of the tumor is:
III (Tumor composed of greater than 50% solid cellular
nests)
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated).
6. Tumor IS identified on the ovarian surface(s).
7. Tumor DOES invade the mesovarium.
8. Tumor DOES NOT invade the adjacent fallopian tube.
9. Tumor DOES invade the pelvic soft tissue.
10. Tumor involvement of the pelvic peritoneum is PRESENT.
11. Metastatic involvement of the EXTRAPELVIC peritoneum
CANNOT BE EVALUATED.
12. Metastatic involvement of the omentum is PRESENT.
14. Metastatic involvement of the uterine serosa is ABSENT.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases CANNOT BE EVALUATED.
17. The total number of regional lymph nodes examined is 0
19. DETAILED STAGING INFORMATION:
Based on the above information, the PRIMARY TUMOR is
classified as:

TNM SCHEME	FIGO SCHEME	DEFINITION
T3c	IIIC	Macroscopic peritoneal metastasis beyond true pelvis measuring greater than 2 cm in greatest dimension

THE REGIONAL LYMPH NODES are classified as:

NX (Nodal status cannot be assessed)

THE STATUS OF DISTANT TUMOR SITES is classified as:

MX (Status cannot be assessed)

20. The FINAL AJCC/FIGO STAGE IS:

AJCC SCHEME	FIGO SCHEME
X	Insufficient data to assign stage

The pathologic stage assigned here should be regarded as
provisional, and may change after integration of clinical
data not provided with this specimen.

History:

The patient is a [REDACTED] with a left adnexal mass.
Operative procedure: Examination under anesthesia, exploratory
laparotomy, total abdominal hysterectomy and bilateral
salpingo-oophorectomy, tumor debulking, omentectomy, and
appendectomy.

Specimen(s) Received:

A: FS1 - OVARY, LEFT
B: X1- OVARY, LEFT
C: TUMOR
D: UTERUS, CERVIX RSO
E: BLADDER TUMOR
F: OMENTUM
G: APPENDIX

[page 3 of 4]
Gross Description:

The specimens are received in seven containers of formalin, each labelled with the patient's name. The first specimen container is labeled "FS1, ovary, left." It contains two unoriented fragments of tan tissue measuring 2.0 x 2.0 x 0.2 cm in aggregate. Labeled [REDACTED]

The second specimen container is labeled "X1, ovary, left." It contains a previously opened and fixed ovary with attached fallopian tube. The ovary measures 5.0 x 2.5 x 2.5 cm. The serosal surface is light blue, glistening, and smooth except for areas where there are well circumscribed yellow, firm nodules suspicious for tumor studding ranging in size from 0.2 to 0.5 cm in greatest dimension. Sections demonstrate a multilobular cavity, measuring 1.5 cm in greatest dimension, containing clear fluid lined by a tan, smooth wall except for areas containing papillary excrescences ranging in size from 0.2 to 1.3 cm in greatest dimension. The excrescences are yellow, firm, and well circumscribed. Labeled X1A to X1E - left ovary. The attached left fallopian tube measures 5.5 cm in length with an external diameter of 0.6 cm. The serosal surface is pale blue, smooth and glistening except for several areas where there are well circumscribed, firm, yellow nodules suspicious for tumor studding ranging in size from 0.2 to 0.6 cm in dimension. Sections demonstrate an unobstructed lumen lined by white tissue. However, there grossly appears to be encroachment of the fallopian tube from the serosal surface by tumor. Labeled X1F - fallopian tube. [REDACTED]

The third specimen container is labeled "tumor." It contains multiple, unoriented fragments of firm, yellow tissue admixed with hemorrhage measuring 8.0 x 4.0 x 3.0 cm. [REDACTED]

The fourth specimen container is labeled "uterus, cervix, and right salpingo-oophorectomy." It contains a uterus with attached right ovary and fallopian tube weighing 140.0 grams and measuring 9.0 cm fundus to ectocervix, 5.5 cm cornu to cornu, and 4.5 cm anterior to posterior. There are numerous leiomyomas distorting the serosal surface ranging in size from 0.5 to 1.6 cm. Sections demonstrate white, firm, whorled tissue without gross evidence of necrosis, softening or hemorrhage. There are numerous fibrinous adhesions covering the posterior serosa of the cervix. However, there is a single area measuring 1.0 cm in greatest dimension suspicious for tumor studding on the deep posterior paracervical soft tissue. The ectocervix measures 4.0 x 2.5 cm. It is light tan, glistening, and smooth. There is a horizontal os with a diameter of 0.3 cm. The endocervical canal is light tan and has a length of 3.5 cm. The myometrium is tan, trabeculated, and has a thickness of 2.0 cm. It is distorted by numerous leiomyomas ranging in size from 0.3 to 2.2 cm in greatest dimension. Sections demonstrate firm, whorled, well circumscribed tissue without gross evidence of necrosis, softening, or hemorrhage. The endometrium is light tan, has a thickness of less than 0.1 cm and measures 3.0 cm cornu to cornu and 4.5 cm fundus to endocervical canal. The attached right ovary measures 2.5 x 2.0 x 1.0 cm. The serosal surface has fibrinous adhesions as well as a single well circumscribed firm, yellow area suspicious for tumor studding measuring 0.6 cm in greatest dimension. Sections demonstrate a unilocular cystic cavity containing clear fluid measuring 1.2 cm in greatest dimension. It is surrounded by white ovarian parenchyma. There is a single excrescence in the cystic cavity measuring 0.2 cm in greatest dimension. The attached right fallopian tube measures 2.5 cm in length with an external diameter of 0.6 cm. There are several fibrinous areas ranging in size from 0.1 to 0.2 cm in greatest dimension of suspicious for adhesions on the serosal surface. Sections demonstrate an unobstructed lumen lined by white tissue. Labeled CX1 - anterior cervix; CX2 - posterior cervix, including area suspicious for serosal tumor studding; EM1 - anterior endometrium including myometrial leiomyoma; EM2 - posterior endometrium including subserosal leiomyoma. Labeled RO1 through RO4 - right ovary. Submitted in toto; RT1 and RT2 - right fallopian tube. [REDACTED]

The fifth specimen container is labeled "bladder tumor." It contains multiple unoriented fragments of white and yellow firm tissue admixed with yellow adipose tissue and hemorrhage measuring 7.0 x 5.0 x 1.5 cm in aggregate. [REDACTED]

The sixth specimen container is labeled "omentum." It contains an

[page 4 of 4]
[REDACTED] **SURGICAL PATHOLOGY REPORT**

unoriented segment of tissue measuring 15.0 x 15.0 x 1.0 cm.
Replacing 95% of the tissue is white, firm tissue suspicious for
tumor. [REDACTED]

The seventh specimen container is labeled "appendix." It contains
an appendix with a stapled base measuring 3.2 cm in length with a
diameter of 0.6 cm. It has a small portion of mesoappendix
attached measuring 4.0 x 0.3 x 0.3 cm. The serosal surface has
hemorrhage, but otherwise it is unremarkable. Sections
demonstrate a lumen lined by white tissue. In some portions of
the lumen there is fecal matter. A longitudinal section is taken
of the tip and shave sections are taken of the base and the middle
of the specimen. [REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 2cbded4f-5750-4829-8a69-be972ecaf7f8 (TCGA-24-1550.7EBD8D19-0A81-4623-8127-F225AD650D46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).